Somatic mutation profile of tumor specimen MP2PRT-PAPHHE-TMP1-A (aliquot MP2PRT-PAPHHE-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PAPHHE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,895 days).
Specimen MP2PRT-PAPHHE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e4184d4-4397-4bbc-9704-1f23fbfbb9a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHHE-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHHE-NM1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84858789-11c5-42c6-afc1-6f5e02beae01

The open-access MAF lists 116 somatic variants for this specimen: 81 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 32, Nonsense Mutation 8, Splice Site 2, Frame Shift Ins 2, Intron 1, Splice Region 1, In Frame Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSG2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 35/383 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs371146201; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 38/618 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 42/540 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACTN2 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 154/357 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs201335965; ClinVar: uncertain significance; called by muse, varscan2
- AKR1C1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 20/383 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1554769934, COSV101080487; called by muse, mutect2
- DEFB118 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV53619535; called by muse, mutect2, varscan2
- DENND10 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.866); catalogued as rs146864091; called by muse, mutect2
- DNAH3 | c.8174C>T p.T2725M | Missense Mutation (SNP) | VAF 195/454 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200636427, COSV54551846; called by muse, mutect2, varscan2
- EPS15 | c.901C>G p.H301D | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV65544918; called by muse, mutect2, varscan2
- GCC2 | c.3565G>C p.E1189Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as COSV59173862; called by muse, varscan2
- GON4L | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV99673702; called by muse, mutect2
- KIAA1522 | c.2540C>T p.S847L (on ENST00000373480 / NM_001198972.2; = p.S906L on NM_020888.3) | Missense Mutation (SNP) | VAF 50/754 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs776125780, COSV53864939; called by muse, mutect2
- MEFV | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 295/671 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1353284079; called by muse, mutect2, varscan2
- NAT16 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 344/825 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1396458548, COSV55865589; called by muse, mutect2, varscan2
- NUP155 | c.1270G>C p.E424Q (on ENST00000231498 / NM_153485.3; = p.E365Q on NM_004298.4) | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV51530630; called by muse, mutect2, varscan2
- NUP214 | c.6061G>A p.A2021T | Missense Mutation (SNP) | VAF 137/334 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs778925867; called by muse, mutect2, varscan2
- OR6B2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 152/379 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs761386136, COSV53152501; called by muse, varscan2
- PAPPA2 | c.4663G>C p.E1555Q | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV100867640, COSV62802503; called by muse, mutect2
- SMG5 | c.1795C>G p.H599D | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62436097; called by muse, mutect2
- TAF1C | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 112/407 reads (28%) | catalogued as rs764729365; called by mutect2, varscan2
- TRPM3 | c.733C>T p.R245* (on ENST00000357533 / NM_001366142.2; = p.R90* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 91/365 reads (25%) | catalogued as rs1165144451; called by muse, mutect2, varscan2
- YAF2 | c.196C>G p.Q66E | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100586422; called by muse, mutect2
- ZFYVE21 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 151/623 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs1173957416; called by muse, mutect2, varscan2
- ZNF461 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as COSV64454675; called by muse, mutect2, varscan2
- ABCG5 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.436); called by muse, mutect2
- ACSM2B | c.1387G>C p.D463H | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ADAMTS19 | c.3355C>G p.Q1119E | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATP1A4 | c.116A>C p.N39T | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- C9orf40 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, varscan2
- CAMSAP2 | c.3646G>A p.E1216K (on ENST00000236925 / NM_001297707.2; = p.E1205K on NM_203459.3) | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- CCDC177 | c.1942G>A p.G648R | Missense Mutation (SNP) | VAF 76/950 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.236); called by muse, mutect2
- CKAP2 | c.110G>C p.R37T | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- CLTRN | c.352C>G p.L118V | Missense Mutation (SNP) | VAF 67/361 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- CNGA1 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COBL | c.3526G>T p.E1176* | Nonsense Mutation (SNP) | VAF 26/440 reads (6%) | called by muse, mutect2
- CRELD2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2
- DSG4 | c.685-1G>T p.X229_splice | Splice Site (SNP) | VAF 37/224 reads (17%) | called by muse, mutect2, varscan2
- ERGIC2 | c.216C>G p.S72R | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- FAM78A | c.432C>G p.I144M | Missense Mutation (SNP) | VAF 28/600 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2
- FGG | c.663G>C p.Q221H | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.18355G>C p.D6119H | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GCC2 | c.3310G>C p.E1104Q | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- GJA8 | c.465C>G p.I155M | Missense Mutation (SNP) | VAF 50/615 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- GRIK2 | c.2086-1G>C p.X696_splice | Splice Site (SNP) | VAF 57/213 reads (27%) | called by muse, mutect2, varscan2
- HNF1B | c.1631C>G p.T544S | Missense Mutation (SNP) | VAF 54/355 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by mutect2, varscan2
- IFNL2 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 65/705 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); called by muse, mutect2
- IGHV1-2 | c.351_352insCCCCGGG | In Frame Ins (INS) | VAF 44/58 reads (76%) | called by mutect2, pindel*, varscan2
- IGHV1-58 | c.348_349insAGACACG p.A117Rfs*? | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | called by mutect2, pindel
- IGHV1-69 | c.350_351delinsTGGGGGG p.R117Mfs*? | Frame Shift Ins (INS) | VAF 34/56 reads (61%) | called by pindel, varscan2*
- IGHV6-1 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- IGSF22 | c.2186G>A p.G729E (on ENST00000319338; = p.G830E on NM_173588.4) | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITLN2 | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- KCTD1 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KIAA1109 | c.2093C>G p.S698* | Nonsense Mutation (SNP) | VAF 67/297 reads (23%) | called by muse, mutect2, varscan2
- KIAA1109 | c.10918G>A p.E3640K | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KSR1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 97/700 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- LRRC3C | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 135/513 reads (26%) | called by muse, mutect2, varscan2
- MAP3K9 | c.1690+3G>A | Splice Region (SNP) | VAF 167/606 reads (28%) | called by muse, mutect2, varscan2
- MUC12 | c.9190G>C p.E3064Q (on ENST00000379442; = p.E2921Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 66/2764 reads (2%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.736); called by muse, mutect2
- PARP4 | c.5024G>A p.W1675* | Nonsense Mutation (SNP) | VAF 41/135 reads (30%) | called by muse, mutect2, varscan2
- PAX9 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 138/668 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- PCLO | c.13043G>A p.R4348K | Missense Mutation (SNP) | VAF 44/464 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, mutect2
- PDZRN3 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 253/549 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PITPNM2 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 105/406 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- RC3H2 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 24/596 reads (4%) | called by muse, mutect2
- SLC12A6 | c.359C>T p.S120F (on ENST00000354181 / NM_001365088.1; = p.S69F on NM_005135.2) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC4A7 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SLMAP | c.1606G>C p.E536Q (on ENST00000428312 / NM_001377924.1; = p.E598Q on NM_007159.5) | Missense Mutation (SNP) | VAF 29/407 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.61); called by muse, mutect2
- SMG5 | c.1361C>G p.S454C | Missense Mutation (SNP) | VAF 29/561 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); called by muse, mutect2
- SMIM14 | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 61/310 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNRNP70 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 147/341 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TATDN2 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 45/481 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- TTN | c.24361C>G p.L8121V (on ENST00000591111; = p.L7194V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/320 reads (45%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBGCP6 | c.4259C>T p.A1420V | Missense Mutation (SNP) | VAF 111/616 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- USP20 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 100/639 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- VSX1 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 35/934 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.096); called by muse, mutect2
- WRN | c.3942G>C p.K1314N | Missense Mutation (SNP) | VAF 190/423 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ZNF451 | c.2725C>T p.Q909* | Nonsense Mutation (SNP) | VAF 55/243 reads (23%) | called by muse, mutect2, varscan2
- ZNF516 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 134/591 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZNF674 | c.1389T>G p.H463Q | Missense Mutation (SNP) | VAF 43/528 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS10 | c.312G>T p.V104= | Silent (SNP) | VAF 254/608 reads (42%) | catalogued as COSV54351785, COSV54357613; called by muse, mutect2, varscan2
- COL22A1 | c.39C>T p.L13= | Silent (SNP) | VAF 110/505 reads (22%) | called by muse, mutect2, varscan2
- CSMD1 | c.63G>C p.A21= | Silent (SNP) | VAF 195/465 reads (42%) | catalogued as COSV68192535; called by muse, mutect2, varscan2
- FAM47C | c.123G>A p.P41= | Silent (SNP) | VAF 311/717 reads (43%) | catalogued as rs782696018, COSV63725468, COSV63731070; called by muse, mutect2, varscan2
- FCRL2 | c.906C>T p.L302= | Silent (SNP) | VAF 32/543 reads (6%) | catalogued as rs1277394781; called by muse, mutect2
- FEZF2 | c.297C>G p.L99= | Silent (SNP) | VAF 58/228 reads (25%) | called by mutect2, varscan2
- FSTL1 | c.639C>G p.L213= | Silent (SNP) | VAF 20/311 reads (6%) | called by muse, mutect2
- HSPA12A | c.1065C>T p.F355= | Silent (SNP) | VAF 78/176 reads (44%) | catalogued as rs782197880, COSV65020744; called by muse, mutect2, varscan2
- IARS1 | c.306C>T p.I102= | Silent (SNP) | VAF 49/204 reads (24%) | called by muse, mutect2, varscan2
- KRT78 | c.354C>G p.L118= | Silent (SNP) | VAF 34/291 reads (12%) | called by muse, mutect2, varscan2
- LLGL2 | c.2439C>T p.V813= | Silent (SNP) | VAF 155/356 reads (44%) | catalogued as rs1213872626; called by muse, mutect2, varscan2
- LRRC69 | c.199C>T p.L67= | Silent (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- MAGEC3 | c.588C>T p.L196= | Silent (SNP) | VAF 36/586 reads (6%) | catalogued as rs1411566598, COSV71610234; called by muse, mutect2
- MTSS2 | c.1380G>A p.Q460= | Silent (SNP) | VAF 26/836 reads (3%) | catalogued as rs1342715686; called by muse, mutect2
- NEMP1 | c.918C>T p.I306= (on ENST00000300128 / NM_001130963.2; = p.I233= on NM_015257.3) | Silent (SNP) | VAF 13/402 reads (3%) | called by muse, mutect2
- NFKB2 | c.1696C>T p.L566= | Silent (SNP) | VAF 126/603 reads (21%) | called by muse, mutect2, varscan2
- OTX2 | c.324G>C p.V108= (on ENST00000408990 / NM_172337.3; = p.V116= on NM_021728.4) | Silent (SNP) | VAF 85/538 reads (16%) | catalogued as COSV59767297; called by muse, mutect2, varscan2
- PCDH19 | c.3223C>T p.L1075= (on ENST00000373034 / NM_001184880.2; = p.L1027= on NM_020766.3) | Silent (SNP) | VAF 52/912 reads (6%) | catalogued as COSV55262442, COSV55263005, COSV55274047; called by muse, mutect2
- PPEF2 | c.1449C>T p.F483= | Silent (SNP) | VAF 54/324 reads (17%) | catalogued as rs972045051, COSV99714426; called by muse, mutect2, varscan2
- PRPF18 | c.669G>A p.Q223= | Silent (SNP) | VAF 94/639 reads (15%) | called by muse, mutect2, varscan2
- RGL3 | c.207G>A p.L69= | Silent (SNP) | VAF 127/493 reads (26%) | called by muse, mutect2, varscan2
- RNF112 | c.801C>G p.L267= | Silent (SNP) | VAF 82/373 reads (22%) | called by muse, mutect2, varscan2
- SLC16A13 | c.804C>T p.V268= | Silent (SNP) | VAF 46/518 reads (9%) | called by muse, mutect2
- SYDE1 | c.984C>G p.L328= | Silent (SNP) | VAF 180/798 reads (23%) | catalogued as rs762705035; called by muse, mutect2, varscan2
- TIAM2 | c.1770C>T p.L590= | Silent (SNP) | VAF 47/360 reads (13%) | called by muse, mutect2, varscan2
- TMEM117 | c.1479C>T p.N493= | Silent (SNP) | VAF 173/392 reads (44%) | catalogued as rs750325679, COSV56896106; called by muse, mutect2, varscan2
- TUBGCP3 | c.2001C>G p.L667= | Silent (SNP) | VAF 61/345 reads (18%) | called by muse, mutect2, varscan2
- UGGT1 | c.1095G>A p.V365= | Silent (SNP) | VAF 38/202 reads (19%) | called by muse, mutect2, varscan2
- UGT2B4 | c.705C>T p.F235= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100522654, COSV59318177; called by muse, mutect2, varscan2
- USP39 | c.171G>A p.A57= | Silent (SNP) | VAF 216/816 reads (26%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.6G>A p.A2= | Silent (SNP) | VAF 70/336 reads (21%) | catalogued as rs1260239284; called by muse, mutect2, varscan2
- ZNF579 | c.927C>T p.L309= | Silent (SNP) | VAF 73/822 reads (9%) | catalogued as rs1013246423; called by muse, mutect2
- C12orf43 | c.146-1297C>G | Intron (SNP) | VAF 69/341 reads (20%) | called by muse, mutect2, varscan2
- NDUFA11 | chr19:5893178 C>G | 3'Flank (SNP) | VAF 35/328 reads (11%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1892G>A | RNA (SNP) | VAF 227/580 reads (39%) | catalogued as rs1401778159, COSV59422539; called by muse, mutect2, varscan2
